Somatic mutation profile of tumor specimen TCGA-CG-5716-01A (aliquot TCGA-CG-5716-01A-21D-1800-08) from TCGA case TCGA-CG-5716, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Gastric antrum; AJCC pathologic stage: Stage IV; Tumor grade: G2; Age at diagnosis: 86.0 years (31,411 days).
Specimen TCGA-CG-5716-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c7779510-8400-4380-ba6a-1924a5b73017.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CG-5716-10A (Blood Derived Normal), aliquot TCGA-CG-5716-10A-01D-1800-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/8c173777-e9b3-4587-9af9-e065ec65f223

The open-access MAF lists 9 somatic variants for this specimen: 8 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 7, Nonsense Mutation 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- DNAH5 | c.8030G>A p.R2677Q | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs886043448, CM1310742, COSV54226107; ClinVar: pathogenic / uncertain significance; called by muse, mutect2
- ATG12 | c.61G>C p.G21R | Missense Mutation (SNP) | VAF 8/132 reads (6%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.726); catalogued as COSV99174635; called by muse, mutect2
- CWF19L2 | c.1511A>G p.E504G | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV99979080; called by muse, mutect2
- DCLK1 | c.1448A>G p.Y483C | Missense Mutation (SNP) | VAF 15/126 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99711410; called by muse, mutect2, varscan2
- DIAPH3 | c.2499C>A p.S833R (on ENST00000400324 / NM_001042517.2; = p.S570R on NM_030932.3) | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99933629; called by muse, mutect2
- DLC1 | c.2640C>G p.D880E (on ENST00000276297 / NM_001348081.2; = p.D443E on NM_006094.5) | Missense Mutation (SNP) | VAF 13/55 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99363330; called by muse, mutect2, varscan2
- DOCK4 | c.4918C>T p.R1640* | Nonsense Mutation (SNP) | VAF 14/282 reads (5%) | catalogued as rs1036832028, COSV101447874; called by muse, mutect2
- MAGEC2 | c.148T>A p.F50I | Missense Mutation (SNP) | VAF 7/118 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.277); catalogued as COSV99909623; called by muse, mutect2
- NTNG2 | c.705G>A p.T235= | Silent (SNP) | VAF 14/129 reads (11%) | catalogued as COSV62367759; called by muse, mutect2, varscan2
